Gene-level copy-number profile of tumor specimen TCGA-43-6771-01A from TCGA case TCGA-43-6771, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 85.0 years (31,052 days).
Specimen TCGA-43-6771-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.e788ab80-44c8-4588-b74d-ae081a840400.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-43-6771-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cf85dd1c-fc74-42df-a459-91a8142cf75b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 16,610; copy number 2: 40,232; copy number 3: 1,346; copy number 4: 1,359; copy number 7: 48; copy number 8: 5; copy number 10: 38; copy number 11: 9; copy number 12: 43; copy number 13: 71; copy number 14: 19; copy number 19: 3; copy number 21: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-43-6771-01A-11D-1816-01): tumor purity 0.48, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,453,802–21,559,900, 1 gene (within-gene range 0–1): MIR31HG.
- chr9:21,512,115–22,128,103, 19 genes: MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 250 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:11,020,883–11,622,005, 9 genes, copy number 13 (within-gene range 3–13): LINC02752, AC111188.1, AC111188.2, MTND5P21, KC877392.1, GALNT18, CSNK2A3, AC023946.1, AC104031.1.
- chr11:13,756,027–13,879,499, 5 genes, copy number 14: CENPUP1, AC013828.1, LINC02548, AC027779.1, LINC02545.
- chr11:14,262,846–14,872,044, 9 genes, copy number 14 (within-gene range 3–14): SPON1-AS1, RRAS2, AC018523.1, COPB1, RNU7-49P, AC018523.2, PSMA1, PDE3B, MORF4L1P3.
- chr11:31,280,672–33,237,409, 43 genes, copy number 12: CYCSP25, AL137804.1, DNAJC24, IMMP1L, ELP4, AC131571.1, PAX6, PAUPAR, AL035078.4, AL035078.1, AL035078.3, AL035078.2, U3, EIF4A2P5, RCN1, AL078612.1, THEM7P, AL078612.2, WT1, WT1-AS, AL049692.6, AL049692.1, AL049692.5, AL049692.3, AL049692.2, AL049692.4, EIF3M, HNRNPA3P9, CCDC73, AL049714.1, PRRG4, QSER1, Y_RNA, DEPDC7, TCP11L1, PIGCP1, LINC00294, CSTF3, CSTF3-DT, Y_RNA, RPL29P23, Y_RNA, AL136126.1.
- chr11:45,921,621–47,594,411, 62 genes, copy number 13 (within-gene range 1–13) (broad region; genes not listed).
- chr11:66,473,490–66,646,469, 14 genes, copy number 11–14 (within-gene range 1–14): AP002748.4, DPP3, AP002748.5, BBS1, AP002748.6, ZDHHC24, ACTN3, AP002748.2, CTSF, CCDC87, CCS, RNU4-39P, RBM14, RBM14-RBM4.
- chr11:68,754,620–71,621,032, 77 genes, copy number 7–21 (broad region; genes not listed).
- chr11:72,576,141–72,674,591, 1 gene, copy number 7 (within-gene range 2–7): PDE2A.
- chr11:72,643,237–73,641,037, 30 genes, copy number 7: PDE2A-AS1, ARAP1, ARAP1-AS1, AP003065.1, ARAP1-AS2, RPS12P20, STARD10, Y_RNA, MIR4692, AP002381.2, ATG16L2, FCHSD2, RNU6-672P, AP002381.1, AP002761.2, AP002761.1, P2RY2, AP002761.4, OR8R1P, P2RY6, AP002761.3, ARHGEF17, RELT, AP000763.4, FAM168A, AP000763.3, AP000763.1, AP000763.2, HMGN2P38, AP000860.1.

Autosomal genes at a single copy (total copy number 1): 14,224. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
